FM case AD6414 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/e2a5c363-a58f-4b21-9131-744f69979a0d

Female, 68.6 years: Carcinosarcoma, NOS (ICD-O-3 8980/3) of the uterus; metastasis biopsied or resected from the cervix uteri. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
